Somatic mutation profile of tumor specimen 0DVBRL from CCDI case PBCMLI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.0 years (3,654 days).
Specimen 0DVBRL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7f2d7d3-1f50-4049-b0c0-5b33f03e4014.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVBRC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20464502-8c3b-487a-87f1-1bd5591197e8

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Nonsense Mutation 3, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 166/384 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, varscan2
- ADAM30 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 142/300 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.157); catalogued as rs775944924, COSV65560771; called by muse, varscan2
- BTN3A1 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.2); catalogued as rs374921833, COSV50024493; called by muse, varscan2
- CSF1R | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 52/347 reads (15%) | catalogued as COSV53838110; called by muse, varscan2
- EPPK1 | c.13951C>T p.R4651W | Missense Mutation (SNP) | VAF 34/317 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.833); catalogued as rs1307224763; called by muse, varscan2
- PPFIA2 | c.3334C>T p.R1112* | Nonsense Mutation (SNP) | VAF 171/560 reads (31%) | catalogued as COSV61056316; called by muse, varscan2
- SKI | c.833C>A p.S278* | Nonsense Mutation (SNP) | VAF 192/224 reads (86%) | catalogued as COSV101049530; called by muse, varscan2
- TBX4 | c.785T>A p.L262Q | Missense Mutation (SNP) | VAF 140/350 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs772580057; called by muse, varscan2
- TMX4 | c.609G>T p.M203I | Missense Mutation (SNP) | VAF 159/321 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs748092194, COSV99851639; called by muse, varscan2
- XCR1 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 150/357 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as rs1367831447, COSV58568837; called by muse, varscan2
- ASH1L | c.3268C>A p.P1090T | Missense Mutation (SNP) | VAF 144/350 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.154); called by muse, varscan2
- DHX8 | c.3598C>A p.P1200T | Missense Mutation (SNP) | VAF 210/494 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- EDA2R | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 148/340 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, varscan2
- FAM50A | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 236/472 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- DCLK2 | c.1494C>T p.N498= | Silent (SNP) | VAF 192/436 reads (44%) | catalogued as rs1360724073, COSV56199337; called by muse, varscan2
- TADA3 | c.936G>A p.K312= | Silent (SNP) | VAF 227/522 reads (43%) | called by muse, varscan2
- STXBP6 | c.-23G>C | 5'UTR (SNP) | VAF 60/127 reads (47%) | catalogued as COSV100121590; called by muse, varscan2
